Somatic mutation profile of tumor specimen 0DRGEZ from CCDI case PBCGBP, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Rhabdomyosarcoma, NOS; Tissue or organ of origin: Accessory sinus, NOS; Age at diagnosis: 19.8 years (7,232 days).
Specimen 0DRGEZ: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f4522d84-c00d-4e2c-9e7c-a8c6386ded14.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DRGEI (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a4bbba82-4d7a-4336-8a35-30a7316147d7

The open-access MAF lists 9 somatic variants for this specimen: 7 protein-altering or splice-affecting, 1 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 6, Splice Region 1, Intron 1, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- MRPL47 | c.721C>G p.L241V | Missense Mutation (SNP) | VAF 135/870 reads (16%) | SIFT tolerated (0.17); PolyPhen benign (0.043); catalogued as COSV99373039; called by muse, varscan2
- SHFL | c.568C>T p.R190C | Missense Mutation (SNP) | VAF 80/214 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.872); catalogued as rs983948136, COSV53461592; called by muse, varscan2
- EPHA3 | c.1279G>T p.A427S | Missense Mutation (SNP) | VAF 254/466 reads (55%) | SIFT tolerated (1); PolyPhen probably damaging (0.985); called by muse, varscan2
- GABRA2 | c.410A>T p.H137L | Missense Mutation (SNP) | VAF 602/1359 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, varscan2
- NLRP2 | c.1664A>T p.Y555F | Missense Mutation (SNP) | VAF 130/370 reads (35%) | SIFT tolerated (0.48); PolyPhen benign (0.191); called by muse, varscan2
- PNPLA7 | c.2337-5T>C | Splice Region (SNP) | VAF 122/180 reads (68%) | called by muse, varscan2
- SPATA31D4 | c.2546G>C p.S849T | Missense Mutation (SNP) | VAF 140/917 reads (15%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.555); called by muse, varscan2
- PRICKLE3 | c.1674G>A p.E558= | Silent (SNP) | VAF 21/167 reads (13%) | catalogued as COSV66234585; called by muse, varscan2
- OAT | c.521-35C>A | Intron (SNP) | VAF 44/363 reads (12%) | called by muse, varscan2
